Gene-level copy-number profile of tumor specimen TCGA-EI-6509-01A from TCGA case TCGA-EI-6509, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma in tubulovillous adenoma; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 53.8 years (19,666 days).
Specimen TCGA-EI-6509-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.32758640-a8ee-4dd9-84c9-4ac3a7dda4dd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EI-6509-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9dcf0621-5dfd-4d11-9e2a-073ea3e2b828

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 2: 12,218; copy number 3: 346; copy number 4: 41,285; copy number 5: 62; copy number 6: 1,029; copy number 7: 3,444; copy number 11: 117; copy number 12: 1,277; copy number 53: 6; copy number 63: 5; copy number 64: 10; copy number 81: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EI-6509-01A-11D-1732-01): tumor purity 0.83, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:50,669,510–51,085,045, 9 genes: AC012433.1, MRO, HNRNPA3P16, RPL17P46, ME2, Y_RNA, ELAC1, AC091551.1, SMAD4.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,426 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 11–12 (broad region; genes not listed).
- chr17:38,297,023–38,674,957, 8 genes, copy number 11–63: MRPL45, GPR179, SOCS7, ARHGAP23, AC244153.1, SRCIN1, AC006449.1, EPOP.
- chr17:38,903,704–38,996,624, 6 genes, copy number 53: AC006441.1, MIR6779, AC006441.3, LINC00672, FBXO47, AC006441.2.
- chr17:39,665,349–39,877,896, 11 genes, copy number 81: TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2.
- chr17:40,850,800–41,004,760, 10 genes, copy number 64: AC004231.4, KRT12, KRT20, AC004231.1, KRT23, KRT39, KRT40, KRTAP3-3, KRTAP3-2, KRTAP3-4P.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
